Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4694, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4694-01A (Primary Tumor).

PART 1:

RENAL VEIN, LEFT, FINAL MARGIN, BIOPSY -

- A. BENIGN SEGMENT OF VEIN.
- B. NO EVIDENCE OF NEOPLASIA SE

TCGA-B0-4694

PART 2:

KIDNEY, LEFT, LAPAROSCOPIC RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA WITH MIXED MORPHOLOGY: PREDOMINANT CONVENTIONAL (CLEAR CELL) TYPE, FOCALLY WITH SARCOMATOID FEATURES AND PAPILLARY CARCINOMA.
- B. FUHRMAN NUCLEAR GRADE IS 4 OF 4.
- C. SARCOMATOID COMPONENT COMPRISES APPROXIMATELY 25% OF TUMOR.
- D. THE GREATEST DIAMETER OF THE NEOPLASM IS 6.0 CM.
- E. THE NEOPLASM EXTENDS INTO THE RENAL SINUS FAT.
- F. ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. CARCINOMA IS PRESENT IN THE LUMEN AND IS ATTACHED TO THE ENDOTHELIUM OF THE RENAL VEIN (SEE PART 1 FOR FINAL MARGIN).
- H. ALL FINAL SURGICAL RESECTION MARGINS ARE NEGATIVE FOR NEOPLASIA.
- I. NON-NEOPLASTIC KIDNEY SHOWS CHANGES DUE TO PROXIMITY THE TUMOR.
- J. UNREMARKABLE ADRENAL GLAND.
- K. TNM STAGE: pT3b NX MX.

Specimen(s) Received: Urine voided / One ThinPrep Slide

Final Diagnosis

Two Clusters of Atypical Transitional Cells.
Transitional Cells.

Source: NCI Genomic Data Commons file b243c70a-acfe-4323-9ad9-9a6e115fc3e1 (TCGA-B0-4694.3E119B2F-288A-42FB-95EE-F2FCEB6F9BE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).